Somatic mutation profile of tumor specimen MP2PRT-PARPMF-TMP1-A (aliquot MP2PRT-PARPMF-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARPMF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,115 days).
Specimen MP2PRT-PARPMF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a15f1c70-15c8-4013-a50c-ec19b70895a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARPMF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARPMF-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8c1bba4-6c27-46ff-a03a-e2a4bbaa2c9d

The open-access MAF lists 37 somatic variants for this specimen: 26 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 23, Silent 11, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.1998G>C p.K666N | Missense Mutation (SNP) | VAF 150/389 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377023736, COSV59205777, COSV59205799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AKIRIN2 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 13/379 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as rs1293864022; called by muse, mutect2
- AKNA | c.3536C>G p.S1179C | Missense Mutation (SNP) | VAF 16/434 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV99800692; called by muse, mutect2
- AL031777.2 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 16/416 reads (4%) | SIFT deleterious, low confidence (0.05); catalogued as COSV100587264, COSV61912013, COSV61912148; called by muse, mutect2
- COL5A2 | c.2545G>A p.G849R | Missense Mutation (SNP) | VAF 80/256 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368239207; called by muse, varscan2
- DUSP16 | c.888G>C p.K296N | Missense Mutation (SNP) | VAF 19/471 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99963466; called by muse, mutect2
- EYA4 | c.1444G>C p.D482H (on ENST00000531901 / NM_001301013.1; = p.D476H on NM_004100.5) | Missense Mutation (SNP) | VAF 74/300 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62063341; called by muse, mutect2, varscan2
- HTRA2 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 65/938 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); catalogued as rs1415691537; called by muse, mutect2
- IRS1 | c.3170C>T p.S1057L | Missense Mutation (SNP) | VAF 76/771 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs746305011; called by muse, mutect2
- ITGA1 | c.2955C>G p.I985M | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV50881703, COSV99251258; called by muse, mutect2, varscan2
- MUC15 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.85); PolyPhen benign (0.009); catalogued as COSV99029003, COSV99846369; called by muse, mutect2, varscan2
- MUC16 | c.26977G>C p.E8993Q | Missense Mutation (SNP) | VAF 213/554 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.636); catalogued as COSV67445630, COSV67471007; called by muse, mutect2
- PLA2G4A | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.162); catalogued as COSV100820577; called by muse, mutect2
- SLC38A4 | c.975C>G p.Y325* | Nonsense Mutation (SNP) | VAF 111/274 reads (41%) | catalogued as COSV99873126; called by muse, mutect2, varscan2
- TMC1 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52781884; called by muse, mutect2
- AMOT | c.522G>C p.L174F | Missense Mutation (SNP) | VAF 21/666 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CHTF18 | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 332/1041 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- F2 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 21/763 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GSPT1 | c.1264G>T p.E422* (on ENST00000420576 / NM_001130007.2; = p.E560* on NM_002094.4) | Nonsense Mutation (SNP) | VAF 9/214 reads (4%) | called by muse, mutect2
- IRAK1BP1 | c.540G>C p.E180D | Missense Mutation (SNP) | VAF 105/263 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- ITGB8 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 17/285 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- JPH4 | c.1448G>A p.G483E | Missense Mutation (SNP) | VAF 24/808 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.108); called by muse, mutect2
- KIAA1210 | c.2744C>T p.S915F | Missense Mutation (SNP) | VAF 212/541 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- NAV2 | c.4894G>C p.E1632Q (on ENST00000396087 / NM_001244963.2; = p.E1609Q on NM_145117.5) | Missense Mutation (SNP) | VAF 17/275 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SMG1 | c.2692C>T p.Q898* | Nonsense Mutation (SNP) | VAF 40/478 reads (8%) | called by muse, mutect2
- TKTL2 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 166/424 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- ACSBG2 | c.1416C>T p.F472= | Silent (SNP) | VAF 168/439 reads (38%) | called by muse, mutect2, varscan2
- ACSBG2 | c.1551C>T p.I517= | Silent (SNP) | VAF 113/321 reads (35%) | called by muse, mutect2, varscan2
- ADGRF3 | c.2553C>T p.L851= (on ENST00000311519 / NM_001145168.1; = p.L652= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/661 reads (4%) | called by muse, mutect2
- F8 | c.15C>T p.L5= | Silent (SNP) | VAF 12/294 reads (4%) | catalogued as COSV64275045; called by muse, mutect2
- FAM167B | c.450C>T p.L150= | Silent (SNP) | VAF 53/976 reads (5%) | catalogued as rs1298393872; called by muse, mutect2
- FAT3 | c.7327C>T p.L2443= | Silent (SNP) | VAF 37/478 reads (8%) | called by muse, mutect2
- NSD1 | c.2601C>G p.L867= | Silent (SNP) | VAF 30/394 reads (8%) | called by muse, mutect2
- PDE2A | c.1944G>A p.K648= | Silent (SNP) | VAF 25/368 reads (7%) | called by muse, mutect2
- PDK4 | c.205C>T p.L69= | Silent (SNP) | VAF 85/251 reads (34%) | called by muse, mutect2, varscan2
- RPTOR | c.936G>A p.L312= | Silent (SNP) | VAF 28/796 reads (4%) | catalogued as COSV60818138; called by muse, mutect2
- SLC24A2 | c.606C>T p.N202= | Silent (SNP) | VAF 115/302 reads (38%) | catalogued as rs147285634, COSV53864646; called by muse, varscan2
